Somatic mutation profile of tumor specimen TCGA-AB-2805-03B (aliquot TCGA-AB-2805-03B-01W-0728-08) from TCGA case TCGA-AB-2805, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.0 years (28,124 days).
Specimen TCGA-AB-2805-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0d2fd23-ee3d-4ab4-ba38-5ed825be98c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2805-11B (Solid Tissue Normal), aliquot TCGA-AB-2805-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ea7971-ac2f-4e33-959e-f4a40faba6bf

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Frame Shift Ins 3, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY3 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs775904787, COSV53173184; called by muse, mutect2, varscan2
- AHNAK | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as COSV99946784, COSV99950197; called by muse, mutect2
- ALMS1 | c.9565C>T p.L3189F | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376367125; called by muse, mutect2, varscan2
- ANKK1 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV100393154; called by muse, mutect2
- BLZF1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs766328635, COSV61394765, COSV99051522; called by muse, mutect2, varscan2
- C1orf216 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV52049070; called by muse, mutect2
- COL5A1 | c.4454C>T p.P1485L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs926801178, COSV65675450; called by muse, mutect2, varscan2
- CSHL1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368319; called by muse, mutect2
- DNAJB1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54318299; called by muse, mutect2
- GGA1 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV100289944; called by muse, mutect2
- GNB1 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66102125; called by muse, mutect2, varscan2
- LTBP3 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV57239899; called by muse, mutect2
- MTUS2 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs371733167; called by muse, mutect2, varscan2
- MYL9 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV54073043; called by muse, mutect2, varscan2
- NFAT5 | c.1835T>A p.V612E | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100591367; called by muse, mutect2
- NFX1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 18/236 reads (8%) | catalogued as rs766710851, COSV59311294; called by muse, mutect2
- PEAR1 | c.1922C>G p.A641G | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV99442615; called by muse, mutect2
- PFKM | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV100402822; called by muse, mutect2
- PHACTR4 | c.1973G>A p.R658Q (on ENST00000373839 / NM_001350159.2; = p.R668Q on NM_023923.4) | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100868513; called by muse, mutect2
- PI4KB | c.1396G>A p.E466K (on ENST00000368873 / NM_001369623.1; = p.E478K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as rs934121209, COSV99650353; called by muse, mutect2
- RUNX1 | c.341dup p.A115Gfs*2 (on ENST00000344691 / NM_001001890.3; = p.A142Gfs*2 on NM_001754.5) | Frame Shift Ins (INS) | VAF 50/105 reads (48%) | catalogued as COSV55867816, COSV55868398, COSV55869747, COSV55877412, COSV55879292, COSV55885154, COSV55888805; called by mutect2, varscan2
- SEH1L | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs1406745898, COSV100040410; called by muse, mutect2
- TNC | c.5611A>G p.K1871E | Missense Mutation (SNP) | VAF 226/502 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1394493737, COSV60791058; called by muse, mutect2, varscan2
- TOP1 | c.831T>A p.N277K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793999; called by mutect2, varscan2
- TRPV5 | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV54689293; called by muse, mutect2
- WDR5 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100682107; called by muse, mutect2
- KRT33A | c.1052_1060del p.C351_N354delinsY | In Frame Del (DEL) | VAF 24/270 reads (9%) | called by mutect2, pindel*
- SLC5A6 | c.1259T>G p.M420R | Missense Mutation (SNP) | VAF 17/614 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- TET3 | c.1135dup p.Q379Pfs*8 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | called by mutect2, pindel
- TRBV2 | c.97_98dup p.Q33Hfs*7 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ANXA13 | c.214C>T p.L72= | Silent (SNP) | VAF 20/492 reads (4%) | catalogued as COSV99147302; called by muse, mutect2
- ARAP3 | c.2064C>T p.V688= | Silent (SNP) | VAF 66/918 reads (7%) | catalogued as COSV99500457; called by muse, mutect2
- DNAI1 | c.1215C>T p.D405= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as rs376177487; ClinVar: likely benign; called by muse, mutect2, varscan2
- FPR1 | c.975C>T p.T325= | Silent (SNP) | VAF 366/774 reads (47%) | catalogued as rs768152901, COSV59053598, COSV59053968; called by mutect2, varscan2
- KIF24 | c.3768C>T p.P1256= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV52662104; called by muse, mutect2, varscan2
- RELN | c.8124T>C p.N2708= | Silent (SNP) | VAF 66/128 reads (52%) | catalogued as COSV59036034; called by muse, varscan2
- RNF26 | c.162T>C p.L54= | Silent (SNP) | VAF 8/280 reads (3%) | catalogued as COSV100264981; called by muse, mutect2
- TTN | c.63943C>T p.L21315= (on ENST00000591111; = p.L13891= on NM_003319.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60373339; called by muse, mutect2, varscan2
- KIR3DX1 | n.615G>A | RNA (SNP) | VAF 96/255 reads (38%) | catalogued as rs766261140, COSV55600052; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331261 C>G | 5'Flank (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
